Somatic mutation profile of tumor specimen TCGA-WK-A8XO-01A (aliquot TCGA-WK-A8XO-01A-11D-A37C-09) from TCGA case TCGA-WK-A8XO, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 66.3 years (24,201 days).
Specimen TCGA-WK-A8XO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7268e437-9054-43c3-b390-d39d8433af5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WK-A8XO-10A (Blood Derived Normal), aliquot TCGA-WK-A8XO-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20decfce-b454-48c9-b017-4d97f3690bcd

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 20, Silent 7, Frame Shift Del 1, Nonsense Mutation 1, Splice Region 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP4 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782787477, COSV62075404; called by muse, mutect2, varscan2
- ARFGAP2 | c.638T>C p.I213T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as rs369493716; called by muse, mutect2, varscan2
- ARG2 | c.861G>A p.G287= | Splice Region (SNP) | VAF 7/16 reads (44%) | catalogued as COSV53619848, COSV99373836; called by muse, mutect2, varscan2
- C7orf25 | c.496A>T p.I166F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.102); catalogued as COSV100623666; called by mutect2, varscan2
- CDH18 | c.1954C>T p.R652W | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs773695784, COSV56899995; called by muse, mutect2, varscan2
- CEP290 | c.5713G>A p.A1905T | Missense Mutation (SNP) | VAF 22/508 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100469603; called by muse, mutect2
- COL4A6 | c.3007G>T p.A1003S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.625); catalogued as COSV100564923; called by muse, mutect2, varscan2
- ELL2 | c.847T>A p.L283M | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99427838; called by muse, mutect2
- GSDMC | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs375510820; called by muse, mutect2, varscan2
- IL27 | c.462+1G>A p.X154_splice | Splice Site (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100112858; called by muse, mutect2, varscan2
- KMT2D | c.11761del p.Q3921Nfs*58 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | catalogued as CM138448; called by mutect2, pindel, varscan2
- MARCHF9 | c.845C>G p.S282* | Nonsense Mutation (SNP) | VAF 13/373 reads (3%) | catalogued as COSV99874985; called by muse, mutect2
- MDN1 | c.9247T>A p.W3083R | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV101021754; called by muse, varscan2
- MINK1 | c.401G>A p.C134Y | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100767267; called by muse, mutect2
- NRIP3 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.877); catalogued as rs746688592, COSV58469024; called by mutect2, varscan2
- NRXN3 | c.1865A>G p.K622R (on ENST00000557594 / NM_001272020.2; = p.K1046R on NM_004796.6) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs200832810, COSV99821335; called by muse, varscan2
- OPHN1 | c.2041G>T p.G681W | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.524); catalogued as COSV100830734; called by muse, mutect2, varscan2
- OR5A2 | c.970G>T p.G324C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.174); catalogued as COSV100119832; called by muse, mutect2, varscan2
- PPP2R2C | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV100067179; called by muse, mutect2, varscan2
- SMR3B | c.221C>A p.P74Q | Missense Mutation (SNP) | VAF 20/54 reads (37%) | PolyPhen probably damaging (0.988); catalogued as COSV100513439, COSV59229452; called by muse, mutect2, varscan2
- TSPAN19 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 172/331 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV101468112; called by muse, mutect2, varscan2
- TYR | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV99635149; called by muse, mutect2, varscan2
- USF3 | c.3328G>A p.E1110K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100325707; called by muse, mutect2, varscan2
- USH2A | c.5620G>A p.V1874I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs200923150, CD1110210, COSV100234763; called by muse, mutect2, varscan2
- ZNF347 | c.2135dup p.N712Kfs*8 | Frame Shift Ins (INS) | VAF 5/56 reads (9%) | called by mutect2, pindel
- ABLIM2 | c.630C>T p.I210= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV99590357; called by muse, mutect2, varscan2
- DIP2B | c.2865T>G p.A955= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99999234; called by muse, mutect2, varscan2
- FBN3 | c.2259C>T p.P753= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs60853419, COSV54456788; called by muse, mutect2, varscan2
- GGTLC2 | c.207C>T p.S69= | Silent (SNP) | VAF 24/200 reads (12%) | catalogued as rs138799771; called by muse, mutect2, varscan2
- MDM2 | c.390G>A p.E130= | Silent (SNP) | VAF 16/573 reads (3%) | catalogued as COSV99254856; called by muse, mutect2
- MSH3 | c.882A>T p.V294= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99435270; called by muse, mutect2, varscan2
- PCDHA5 | c.1236G>A p.L412= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV100972506; called by muse, mutect2, varscan2
